Surgical pathology report (de-identified scan), TCGA case TCGA-61-1907, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1907-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA IN OMENTUM.

PART 2: UTERUS, CERVIX (226 GRAMS), RIGHT AND LEFT FALLOPIAN TUBES AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY –

- A. CHRONIC CERVICITIS.
- B. UTERUS WITH METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING THE SEROSA AND MYOMETRIUM.
- C. PAPILLARY SEROUS CARCINOMA INVASION OF LYMPHOVASCULAR SPACES IS IDENTIFIED.
- D. ATROPHIC ENDOMETRIUM.
- E. SESSILE ENDOMETRIAL POLYP.
- F. LEIOMYOMATA.
- G. POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA INVOLVING THE LEFT OVARY AND LEFT FALLOPIAN TUBE (11.0 X 6.0 X 4.0 CM).
- H. RIGHT OVARY WITH METASTATIC PAPILLARY SEROUS CARCINOMA, LYMPHOVASCULAR INVASION AND BENIGN SEROUS CYST.
- I. RIGHT FALLOPIAN TUBE, NEGATIVE FOR TUMOR.

PART 3: TUMOR, DEBULKING (PELVIC AREA) –

METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA.

PART 4: APPENDIX, APPENDECTOMY –

- A. METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING THE MESOSALPINX AND IN LYMPHOVASCULAR SPACES.
- B. FIBROUS OBLITERATION OF THE LUMEN.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS
TUMOR LOCATION: Bilateral

PROCEDURE: TAH with salpingo-oophorectomy

TUMOR SIZE: Maximum dimension: 11 cm

TUMOR TYPE: Papillary serous carcinoma

HISTOLOGIC SILVERBERG GRADE: Poorly differentiated (8-9 pts)

ARCHITECTURAL PATTERN: Papillary (2)

CYTOLOGIC ATYPIA: Marked (3)

MITOTIC COUNTS / 10hpf: 10-24 (2)

VASCULAR INVASION: Yes

TUMOR CAPSULE: Ruptured

SURFACE IMPLANTS: Invasive

SURFACE IMPLANT SITE: Uterus, Fallopian Tubes, Omentum

SURFACE IMPLANT SIZE: > 2 cm.

ASSOCIATED OTHER LESION: Atypia of surface epithelium or surface epithelial inclusion

MALIGNANT CELLS IN ASCITES OR

PERITONEAL WASHING: No

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 0

LYMPH NODES POSITIVE: Number of positive lymph nodes, Right: 0

Number of positive lymph nodes, Left: 0

EXTRANODAL EXTENSION: No

T STAGE, PATHOLOGIC: pT3c

N STAGE, PATHOLOGIC: pNX

M STAGE, PATHOLOGIC: pMX

FIGO STAGE: IIIC

Source: NCI Genomic Data Commons file 97305180-cd5a-4a87-8b6a-c4996e81eb47 (TCGA-61-1907.AE7E4795-496E-47D0-AD60-CEC04E5876B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).